Gene-level copy-number profile of tumor specimen TCGA-EY-A214-01A from TCGA case TCGA-EY-A214, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 66.1 years (24,136 days).
Specimen TCGA-EY-A214-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.30bf82ef-59e9-426d-8ad1-be329b70b63c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A214-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcc6392d-3f30-456b-822f-fa312b11fee5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,501; copy number 3: 16,668; copy number 4: 12,452; copy number 5: 8,708; copy number 6: 8,863; copy number 7: 2,715; copy number 8: 3,864; copy number 9: 1,940; copy number 10: 796; copy number 11: 254; copy number 13: 4; copy number 17: 12; copy number 18: 36; copy number 40: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A214-01A-12D-A160-01): tumor purity 0.75, ploidy 1.57, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 9,626 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 8 (broad region; genes not listed).
- chr2:38,814–8,488,090, 115 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).
- chr3:87,594,838–198,222,513, 1,827 genes, copy number 7–11 (broad region; genes not listed).
- chr4:43,340,875–46,124,054, 27 genes, copy number 7 (within-gene range 4–7): AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1.
- chr6:167,607–28,649,538, 609 genes, copy number 7 (broad region; genes not listed).
- chr6:32,439,878–47,722,021, 434 genes, copy number 8 (broad region; genes not listed).
- chr6:128,883,138–131,951,372, 38 genes, copy number 7: LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2.
- chr8:36,378,069–50,796,692, 253 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:99,013,266–99,877,580, 1 gene, copy number 11 (within-gene range 4–11): VPS13B.
- chr8:99,233,048–137,105,458, 501 genes, copy number 7–11 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 9–10 (broad region; genes not listed).
- chr11:101,451,564–102,001,062, 6 genes, copy number 7: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126.
- chr12:19,089,151–26,833,194, 121 genes, copy number 7–17 (broad region; genes not listed).
- chr12:30,086,342–30,296,707, 4 genes, copy number 8: AC023511.3, AC023511.2, AC023511.1, LINC02386.
- chr12:66,950,754–93,215,679, 353 genes, copy number 9 (broad region; genes not listed).
- chr13:18,467,172–25,366,155, 193 genes, copy number 8 (broad region; genes not listed).
- chr13:32,303,699–37,221,246, 73 genes, copy number 11–40 (broad region; genes not listed).
- chr13:92,239,835–114,337,626, 334 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
